Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3531, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3531-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Resectate of the colon (sigmoid colon) with diverticulosis, with tumor-free oral and aboral resection margins and under inclusion of an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue. Thirty-seven regional lymph nodes tumor-free, with uncharacteristic reactive changes (G2, pT3 pN0 (0/37) L0 V0 R0).

Source: NCI Genomic Data Commons file 9fb4651e-99be-459b-a0ea-404781c52598 (TCGA-AA-3531.ADF38D8C-1CDE-4C59-B54E-D498E2A96FF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).